Somatic mutation profile of tumor specimen TARGET-10-PARUBU-09A (aliquot TARGET-10-PARUBU-09A-01D) from TARGET case TARGET-10-PARUBU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,134 days).
Specimen TARGET-10-PARUBU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 738662bb-c1e1-4791-9ba8-d26e9c890014.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUBU-14A (Bone Marrow Normal), aliquot TARGET-10-PARUBU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/604fd145-a365-4f37-bfa4-b823f8efad95

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2, Intron 2, 3'Flank 1, 3'UTR 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCE1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as rs121912601, CM066174, COSV53369456; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PNLIPRP2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1198140788, COSV53942794; called by muse, mutect2, varscan2
- PROX1 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV54783011; called by muse, mutect2, varscan2
- SLC17A6 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs878877170, COSV54134483; called by muse, mutect2
- ARHGAP4 | c.990T>A p.C330* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- DISP2 | c.2612T>A p.F871Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FAM83B | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- GLUD2 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGLV4-69 | c.355_356del p.I119Sfs*? | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by pindel*, varscan2
- KBTBD3 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- KCNT2 | c.2060T>C p.L687P | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR10K1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2
- PROX1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CDK17 | c.1131C>T p.C377= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- CIITA | c.615C>T p.T205= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs749376450; called by muse, mutect2, varscan2
- ESPL1 | c.2538C>T p.L846= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs761589487; called by muse, mutect2, varscan2
- PROX1 | c.222G>A p.L74= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ZNF423 | c.3840C>T p.T1280= (on ENST00000563137 / NM_001379286.1; = p.T1272= on NM_015069.4) | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs779049571, COSV52203337; called by muse, mutect2
- DDX6 | c.865-11T>A | Intron (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- FSIP2 | c.*14G>A | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- IGKV4-1 | chr2:88886153 ins CCCC | 3'Flank (INS) | VAF 17/31 reads (55%) | called by mutect2, pindel, varscan2
- LZTS2 | c.-39G>A | 5'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs771772821, COSV100932124; called by muse, mutect2
- SLC25A39 | c.883+17C>T | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
